Somatic mutation profile of tumor specimen TCGA-B0-5096-01A (aliquot TCGA-B0-5096-01A-01D-1421-08) from TCGA case TCGA-B0-5096, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 72.8 years (26,574 days).
Specimen TCGA-B0-5096-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee855948-a77d-4bbf-ac9d-67a53a370dff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5096-11A (Solid Tissue Normal), aliquot TCGA-B0-5096-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a7a138f-507e-428d-87d4-e29c6215690d

The open-access MAF lists 102 somatic variants for this specimen: 72 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 28, Nonsense Mutation 5, Frame Shift Del 5, Splice Site 4, Frame Shift Ins 2, Translation Start Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TCF12 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880016, CM1411541, COSV51003557, COSV99032766; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VHL | c.341-1G>T p.X114_splice | Splice Site (SNP) | VAF 70/268 reads (26%) | hotspot (GDC flag); catalogued as CS014769, CS107609, CS984220, COSV56543442, COSV56544761, COSV56548789; called by muse, mutect2, varscan2
- A4GNT | c.802T>G p.W268G | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52628433; called by muse, mutect2, varscan2
- ALB | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55735952; called by muse, mutect2, varscan2
- ASH2L | c.402-1G>T p.X134_splice | Splice Site (SNP) | VAF 31/182 reads (17%) | catalogued as COSV51698536; called by muse, mutect2, varscan2
- BAP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV56230747; called by muse, mutect2, varscan2
- BDKRB1 | c.297C>G p.N99K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV53705322; called by muse, mutect2, varscan2
- CDC27 | c.1470T>A p.H490Q | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV50364755; called by muse, mutect2, varscan2
- CDCA2 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs537909463, COSV57944393; called by muse, mutect2
- COL4A5 | c.4511-1G>T p.X1504_splice | Splice Site (SNP) | VAF 43/197 reads (22%) | catalogued as COSV60356298; called by muse, mutect2, varscan2
- COL4A6 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1453673529, COSV57858880; called by muse, mutect2, varscan2
- CYBRD1 | c.858G>A p.M286I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV58425874; called by muse, mutect2, varscan2
- DNAJC13 | c.6381+1G>A p.X2127_splice | Splice Site (SNP) | VAF 37/165 reads (22%) | catalogued as COSV53445859; called by muse, mutect2, varscan2
- EHMT2 | c.1979A>G p.Q660R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV64994603; called by muse, mutect2, varscan2
- ERICH1 | c.980A>T p.E327V | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV50637235; called by muse, mutect2, varscan2
- FAM9A | c.423T>A p.D141E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV66812948; called by muse, mutect2, varscan2
- FNBP1L | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774614978, COSV53091412; called by muse, mutect2
- FOXP4 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV57218335; called by muse, mutect2, varscan2
- GCC2 | c.3574A>G p.I1192V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs1039516171, COSV59174061; called by muse, mutect2, varscan2
- GOT2 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 113/580 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs199949591; called by muse, mutect2, varscan2
- GPX8 | c.571A>G p.R191G | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs1331907181, COSV57049756; called by muse, mutect2, varscan2
- GSS | c.542C>A p.S181Y | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV53811640; called by muse, mutect2, varscan2
- HERC1 | c.6890G>T p.R2297M | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV71245979; called by muse, mutect2, varscan2
- JPT2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1465148166, COSV50188509; called by muse, mutect2, varscan2
- KCNH7 | c.2729C>G p.P910R | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV59785418, COSV59786460; called by muse, mutect2, varscan2
- KIR2DL1 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 111/618 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as rs1200918983, COSV99383743; called by muse, mutect2, varscan2
- KMT2C | c.10814A>T p.K3605I | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51297420; called by muse, mutect2
- LAMB4 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.469); catalogued as COSV52713531; called by muse, mutect2, varscan2
- MLXIPL | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57666816; called by muse, mutect2, varscan2
- MORC1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs764044599, COSV51714138, COSV99227463; called by muse, mutect2, varscan2
- MTMR1 | c.818A>C p.D273A | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64892215; called by muse, varscan2
- MUC6 | c.6467C>G p.S2156W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV70134012; called by muse, mutect2, varscan2
- NAALAD2 | c.1497G>T p.L499F | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV58958741; called by muse, mutect2, varscan2
- NLRC3 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV57087207; called by muse, mutect2, varscan2
- NLRC3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV57087246; called by muse, mutect2, varscan2
- NSD2 | c.1300G>C p.G434R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs1560642259, COSV56386647; called by muse, mutect2, varscan2
- OR12D3 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV65826398; called by muse, mutect2, varscan2
- OSBPL8 | c.796T>C p.C266R | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53878194; called by muse, mutect2, varscan2
- OTX1 | c.278G>C p.C93S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV56993652, COSV99246183; called by muse, mutect2, varscan2
- PBRM1 | c.1757T>A p.M586K | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV56261504, COSV56265358; called by muse, mutect2, varscan2
- PBX2 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV66708685; called by muse, mutect2, varscan2
- PDYN | c.621T>A p.Y207* | Nonsense Mutation (SNP) | VAF 52/280 reads (19%) | catalogued as COSV54100802; called by muse, mutect2, varscan2
- PKNOX1 | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 181/795 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52334203; called by muse, mutect2
- PNPLA4 | c.331C>A p.L111M | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66853740; called by muse, mutect2, varscan2
- PROC | c.1369A>C p.K457Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV52164782; called by muse, mutect2, varscan2
- PSAPL1 | c.362T>C p.M121T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV59842289; called by muse, mutect2
- RBM15 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63923046; called by muse, mutect2, varscan2
- SIGLEC8 | c.399G>C p.W133C | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV58471921; called by muse, mutect2, varscan2
- SLC39A10 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 45/183 reads (25%) | catalogued as COSV62766310; called by muse, mutect2, varscan2
- SLC9A9 | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); catalogued as COSV57218584; called by muse, mutect2, varscan2
- SNRNP48 | c.767G>A p.W256* | Nonsense Mutation (SNP) | VAF 31/150 reads (21%) | catalogued as COSV60938571; called by muse, mutect2, varscan2
- THOC3 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV54197503; called by mutect2, varscan2
- TP53BP1 | c.2630C>G p.S877* | Nonsense Mutation (SNP) | VAF 27/310 reads (9%) | catalogued as COSV55496499; called by muse, mutect2
- TRABD2A | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 113/485 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59101739; called by muse, mutect2, varscan2
- TTN | c.85673G>A p.G28558E (on ENST00000591111; = p.G21134E on NM_003319.4) | Missense Mutation (SNP) | VAF 48/190 reads (25%) | PolyPhen possibly damaging (0.866); catalogued as rs757271306, COSV59893411; called by muse, mutect2, varscan2
- TTN | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 77/425 reads (18%) | PolyPhen benign (0.292); catalogued as COSV59893457; called by muse, mutect2, varscan2
- TXNRD2 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.891); catalogued as rs745523977, COSV57632008; called by muse, mutect2, varscan2
- VARS2 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 71/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52557719; called by muse, mutect2, varscan2
- VPS13D | c.10337C>G p.P3446R | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50622143; called by muse, mutect2, varscan2
- XRN1 | c.4943A>G p.E1648G | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV53808019; called by muse, mutect2
- ZC3HC1 | c.665A>T p.E222V | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61297237; called by muse, mutect2, varscan2
- ZC3HC1 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 33/221 reads (15%) | catalogued as COSV61297263; called by muse, mutect2, varscan2
- ZFHX4 | c.8911C>T p.R2971C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50500468, COSV50602092; called by muse, mutect2, varscan2
- ZHX2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.15); catalogued as COSV58710305; called by muse, mutect2, varscan2
- ADAM32 | c.1884dup p.Q629Tfs*9 | Frame Shift Ins (INS) | VAF 39/247 reads (16%) | called by mutect2, pindel, varscan2
- CCBE1 | c.248del p.G83Dfs*111 | Frame Shift Del (DEL) | VAF 21/147 reads (14%) | called by mutect2, pindel, varscan2
- CEP290 | c.3972del p.K1324Nfs*2 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | called by mutect2, pindel, varscan2
- FN3K | c.547dup p.D183Gfs*4 | Frame Shift Ins (INS) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- GAL3ST4 | c.647_650del p.L216Pfs*106 | Frame Shift Del (DEL) | VAF 43/275 reads (16%) | called by mutect2, pindel, varscan2
- PPIL4 | c.1169_1170del p.H390Pfs*4 | Frame Shift Del (DEL) | VAF 66/432 reads (15%) | called by mutect2, pindel, varscan2
- SLC2A1 | c.1253T>C p.V418A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TMEM145 | c.737_743del p.L246Pfs*9 | Frame Shift Del (DEL) | VAF 15/164 reads (9%) | called by mutect2, pindel
- ABCG2 | c.1659T>C p.G553= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs1347395666, COSV52943122; called by muse, mutect2, varscan2
- ADGRE1 | c.111C>T p.D37= | Silent (SNP) | VAF 58/362 reads (16%) | catalogued as rs1173223315, COSV51672122; called by muse, mutect2, varscan2
- ARHGAP11B | c.33G>T p.L11= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs889363319, COSV70288291; called by muse, mutect2, varscan2
- ATP1B4 | c.618C>T p.Y206= (on ENST00000218008 / NM_001142447.3; = p.Y202= on NM_012069.5) | Silent (SNP) | VAF 61/314 reads (19%) | catalogued as COSV54311236; called by muse, mutect2, varscan2
- BBS2 | c.1149C>T p.L383= | Silent (SNP) | VAF 44/277 reads (16%) | catalogued as COSV55325128; called by muse, mutect2, varscan2
- CAPZA2 | c.150A>T p.A50= | Silent (SNP) | VAF 30/219 reads (14%) | catalogued as COSV63265927; called by muse, mutect2, varscan2
- CCNF | c.1953G>A p.Q651= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53537852; called by muse, mutect2, varscan2
- CCNI | c.843C>A p.P281= | Silent (SNP) | VAF 59/262 reads (23%) | catalogued as COSV52959186; called by muse, mutect2, varscan2
- CELF4 | c.516C>T p.F172= | Silent (SNP) | VAF 52/242 reads (21%) | catalogued as COSV58446868; called by muse, mutect2, varscan2
- CPSF7 | c.159T>G p.P53= (on ENST00000394888 / NM_001136040.4; = p.P96= on NM_024811.4) | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV61210155; called by muse, mutect2, varscan2
- DLX4 | c.360G>C p.P120= (on ENST00000240306 / NM_138281.3; = p.P48= on NM_001934.3) | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV53591049; called by muse, mutect2, varscan2
- GNAI3 | c.792C>T p.I264= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as COSV63983269; called by muse, mutect2, varscan2
- IGKV2D-29 | c.165G>A p.K55= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV101534402, COSV72391645; called by muse, mutect2, varscan2
- LAMB1 | c.2700T>C p.A900= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV55961690; called by muse, mutect2, varscan2
- LAMB3 | c.1683G>A p.G561= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV61915377; called by muse, varscan2
- LARS1 | c.45G>A p.K15= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV50972254, COSV50975165; called by muse, mutect2, varscan2
- LZTS1 | c.1743G>A p.L581= | Silent (SNP) | VAF 50/188 reads (27%) | catalogued as COSV56115784; called by muse, mutect2, varscan2
- MPPED2 | c.228T>A p.P76= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as COSV63896153; called by muse, mutect2, varscan2
- NFYC | c.375T>G p.P125= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV58125785; called by muse, mutect2, varscan2
- NUTM2D | c.843C>G p.T281= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as COSV101097046; called by mutect2, varscan2
- OPA1 | c.1092C>G p.A364= (on ENST00000361510 / NM_130837.3; = p.A309= on NM_015560.3) | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV62478988; called by muse, mutect2
- PEG3 | c.2349C>A p.A783= | Silent (SNP) | VAF 140/677 reads (21%) | catalogued as COSV55625019; called by muse, mutect2, varscan2
- SLC35F5 | c.210T>G p.A70= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV55516876; called by muse, mutect2, varscan2
- STYXL2 | c.1533A>C p.A511= | Silent (SNP) | VAF 31/190 reads (16%) | catalogued as COSV54802112; called by muse, mutect2, varscan2
- TTN | c.20880C>T p.N6960= (on ENST00000591111; = p.N6033= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs1481732672, COSV59893436; called by muse, mutect2, varscan2
- USP40 | c.2169T>C p.I723= | Silent (SNP) | VAF 81/394 reads (21%) | catalogued as COSV52477336; called by muse, mutect2, varscan2
- VARS2 | c.711T>C p.G237= | Silent (SNP) | VAF 72/306 reads (24%) | catalogued as COSV52557732; called by muse, mutect2, varscan2
- ZNF124 | c.162C>T p.N54= | Silent (SNP) | VAF 21/164 reads (13%) | catalogued as COSV61506826; called by muse, mutect2, varscan2
- MIR222 | n.60G>A | RNA (SNP) | VAF 11/52 reads (21%) | catalogued as rs72631825; called by muse, mutect2, varscan2
- NACA | c.71-4659T>A | Intron (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100771742; called by muse, mutect2
